Somatic mutation profile of tumor specimen 0DLFB2 from CCDI case PBBXEA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Synovial sarcoma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 22.6 years (8,246 days).
Specimen 0DLFB2: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d52754c5-60ad-4617-b378-3e3e0c9d1816.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DLFAW (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2dc3b23a-250f-41e0-aeb2-9e7e2e4d8fa3

The open-access MAF lists 12 somatic variants for this specimen: 6 protein-altering or splice-affecting, 3 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 3, Intron 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CNGA4 | c.647G>A p.R216H | Missense Mutation (SNP) | VAF 363/729 reads (50%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.581); catalogued as rs1353756952, COSV66006345; called by muse, mutect2, varscan2
- GGT1 | c.1507C>T p.R503W | Missense Mutation (SNP) | VAF 255/865 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs762681085; called by muse, mutect2, varscan2
- ACP4 | c.322G>A p.D108N | Missense Mutation (SNP) | VAF 30/654 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- FPGT-TNNI3K | c.957C>G p.H319Q | Missense Mutation (SNP) | VAF 316/834 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); called by muse, mutect2, varscan2
- PCDH8 | c.2371C>G p.R791G | Missense Mutation (SNP) | VAF 171/309 reads (55%) | SIFT tolerated (0.2); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- SH2D4A | c.1246T>G p.L416V | Missense Mutation (SNP) | VAF 138/847 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ANKRD42 | c.996C>T p.D332= | Silent (SNP) | VAF 310/746 reads (42%) | catalogued as rs143312508; called by muse, mutect2, varscan2
- CISD2 | c.271T>C p.L91= | Silent (SNP) | VAF 419/1059 reads (40%) | called by muse, mutect2, varscan2
- SORL1 | c.2430C>T p.D810= | Silent (SNP) | VAF 411/1023 reads (40%) | catalogued as rs370375010; called by muse, mutect2, varscan2
- LILRB5 | c.1629+11G>A | Intron (SNP) | VAF 73/239 reads (31%) | catalogued as rs780619979; called by muse, mutect2, varscan2
- SF3A2 | c.245+44G>A | Intron (SNP) | VAF 43/170 reads (25%) | catalogued as rs367545836; called by muse, mutect2, varscan2
- SPACA7 | c.*71G>C | 3'UTR (SNP) | VAF 85/185 reads (46%) | called by muse, mutect2, varscan2
